Somatic mutation profile of tumor specimen TCGA-B9-4114-01A (aliquot TCGA-B9-4114-01A-01D-1252-08) from TCGA case TCGA-B9-4114, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 49.3 years (17,989 days).
Specimen TCGA-B9-4114-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0760391-5cef-4feb-aa3a-c6cca169ebe0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4114-10A (Blood Derived Normal), aliquot TCGA-B9-4114-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a62b2663-e4e0-45a7-b9ae-97a12644e709

The open-access MAF lists 79 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 14, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 2, In Frame Del 1, 3'Flank 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.2083G>A p.G695S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52637120; called by muse, mutect2
- AGPAT5 | c.900T>A p.D300E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as COSV53447892; called by muse, mutect2, varscan2
- ANKDD1A | c.1247G>T p.W416L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV63088021; called by mutect2, varscan2
- ATP1A1 | c.689A>C p.D230A | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55192401; called by muse, mutect2, varscan2
- ATP4A | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52869306; called by muse, mutect2, varscan2
- ATXN7L3 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 57/315 reads (18%) | catalogued as COSV66989325; called by muse, mutect2, varscan2
- CAPN13 | c.1882T>A p.F628I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99700334; called by muse, mutect2, varscan2
- CCAR2 | c.185T>A p.V62D | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51515964; called by muse, mutect2, varscan2
- DNAH17 | c.11144A>G p.Y3715C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV67757643; called by muse, mutect2
- EIF3M | c.1078A>T p.N360Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV58800866; called by muse, mutect2, varscan2
- FAU | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV54195362; called by muse, mutect2, varscan2
- FNIP1 | c.3086C>T p.S1029L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV57197927; called by muse, mutect2, varscan2
- FNIP1 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57197935; called by muse, mutect2, varscan2
- GLI1 | c.940C>A p.R314S | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57357532, COSV57359048, COSV57364183; called by muse, mutect2, varscan2
- GPAT3 | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV52358087; called by muse, mutect2, varscan2
- GRAMD4 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs371794625; called by muse, mutect2, varscan2
- HLA-DQA2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66565927; called by muse, varscan2
- IFT57 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52710510; called by muse, mutect2, varscan2
- KCNS2 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 52/200 reads (26%) | catalogued as COSV54639393, COSV99751133; called by muse, mutect2, varscan2
- KCTD8 | c.757A>C p.N253H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63591584; called by muse, mutect2, varscan2
- KMT2C | c.5051A>C p.K1684T | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51460197; called by muse, mutect2, varscan2
- LEMD2 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53394438; called by muse, mutect2, varscan2
- LINS1 | c.1044del p.L349Cfs*2 | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | catalogued as rs771584040; called by mutect2, pindel, varscan2
- LNX1 | c.1720G>A p.A574T (on ENST00000263925 / NM_001126328.3; = p.A478T on NM_032622.2) | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55788119; called by muse, mutect2, varscan2
- NODAL | c.509A>T p.E170V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV54661881; called by muse, mutect2, varscan2
- NOLC1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV64180700; called by muse, mutect2, varscan2
- NR2F1 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 119/391 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV59069260, COSV59070267; called by muse, mutect2, varscan2
- OAF | c.422A>C p.H141P | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as COSV61109531; called by muse, mutect2, varscan2
- OAF | c.423C>A p.H141Q | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV61109536; called by muse, mutect2, varscan2
- PALB2 | c.1460T>A p.V487D | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.9); catalogued as COSV55166900; called by muse, mutect2, varscan2
- PARP8 | c.2048T>A p.F683Y | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV55862449; called by muse, mutect2, varscan2
- PEBP1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54337382; called by muse, mutect2, varscan2
- PGLYRP3 | c.138C>G p.Y46* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as rs1480526679, COSV51951252; called by muse, mutect2, varscan2
- PLCB2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201305253, COSV53034165; called by muse, mutect2, varscan2
- RARRES1 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as COSV52962991; called by muse, mutect2, varscan2
- RNF31 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53760359; called by muse, mutect2, varscan2
- RNF40 | c.796A>T p.T266S | Missense Mutation (SNP) | VAF 79/297 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.875); catalogued as COSV61215522; called by muse, mutect2, varscan2
- ROS1 | c.56G>C p.C19S | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs747481675, COSV63857304; called by muse, mutect2, varscan2
- SAXO2 | c.473A>C p.H158P | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59754450; called by muse, mutect2, varscan2
- SERPINA1 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV63345901; called by muse, mutect2, varscan2
- SGIP1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.987); catalogued as COSV52772919; called by muse, mutect2, varscan2
- SH3BP2 | c.1140dup p.V381Rfs*14 | Frame Shift Ins (INS) | VAF 56/139 reads (40%) | catalogued as rs759199606; called by mutect2, pindel, varscan2
- SMARCC2 | c.3343A>C p.N1115H | Missense Mutation (SNP) | VAF 104/246 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV53239857; called by muse, mutect2, varscan2
- SP140 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV59451764; called by muse, mutect2, varscan2
- SPATA20 | c.1253G>C p.G418A (on ENST00000356488 / NM_001258372.1; = p.G434A on NM_022827.4) | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV50067842; called by mutect2, varscan2
- TFR2 | c.1175G>A p.G392D | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); catalogued as rs771358868, COSV56155103; called by muse, mutect2, varscan2
- TMEM184A | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV52474371; called by muse, mutect2, varscan2
- TMX2 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.756); catalogued as COSV53555145; called by muse, mutect2, varscan2
- TNKS | c.235C>G p.R79G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs764665125, COSV60052105, COSV60061633; called by muse, mutect2, varscan2
- TTBK1 | c.3217C>A p.L1073M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV52493539; called by muse, mutect2, varscan2
- UBR4 | c.13819C>A p.R4607S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64393062; called by muse, mutect2, varscan2
- UNC13B | c.1333A>G p.M445V | Missense Mutation (SNP) | VAF 216/356 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs754993902, COSV65936098; called by muse, mutect2, varscan2
- ZNF14 | c.1010G>T p.C337F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59850298; called by muse, varscan2
- ZSWIM1 | c.914A>T p.N305I | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV54849077; called by muse, mutect2, varscan2
- ZYG11B | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV53754427; called by muse, mutect2, varscan2
- IRF2BP2 | c.1589_1591del p.C530del | In Frame Del (DEL) | VAF 71/290 reads (24%) | called by mutect2, pindel, varscan2
- ISLR2 | c.157del p.V53* | Frame Shift Del (DEL) | VAF 63/232 reads (27%) | called by mutect2, pindel, varscan2
- ITM2B | c.366_367insCAA p.F122_E123insQ | In Frame Ins (INS) | VAF 30/79 reads (38%) | called by mutect2, varscan2
- MYO1H | c.421del p.T141Pfs*4 | Frame Shift Del (DEL) | VAF 18/128 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGA12 | c.847_853del p.Y283Tfs*10 | Frame Shift Del (DEL) | VAF 63/232 reads (27%) | called by mutect2, pindel, varscan2
- TNC | c.5937del p.F1980Sfs*10 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- TOGARAM1 | c.1905del p.H635Qfs*16 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ZCCHC8 | c.1044dup p.G349Wfs*7 | Frame Shift Ins (INS) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- ABL1 | c.1032C>T p.A344= | Silent (SNP) | VAF 87/141 reads (62%) | catalogued as COSV59334751; called by muse, mutect2, varscan2
- BCAR3 | c.732G>A p.Q244= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV53076546; called by muse, mutect2, varscan2
- BRSK2 | c.912C>T p.D304= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV57545044; called by muse, mutect2, varscan2
- C12orf66 | c.192C>G p.A64= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1286505020, COSV61323800; called by muse, varscan2
- ERBB2 | c.1939A>C p.R647= | Silent (SNP) | VAF 75/404 reads (19%) | catalogued as COSV54068520, COSV54074855; called by muse, mutect2, varscan2
- EVC | c.279G>A p.S93= | Silent (SNP) | VAF 171/406 reads (42%) | catalogued as rs373072919; called by muse, mutect2, varscan2
- FAU | c.18C>A p.R6= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV54195359; called by muse, mutect2, varscan2
- KCTD8 | c.756C>T p.L252= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV63591586; called by muse, mutect2, varscan2
- PARP4 | c.837A>G p.E279= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67962883; called by muse, mutect2, varscan2
- POU5F2 | c.588T>A p.L196= | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as COSV67939424; called by muse, mutect2, varscan2
- RAI14 | c.132C>T p.A44= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV54297937; called by muse, mutect2, varscan2
- SEMA5A | c.1815T>A p.S605= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV66798307; called by muse, mutect2, varscan2
- UBOX5 | c.1435C>T p.L479= | Silent (SNP) | VAF 89/225 reads (40%) | catalogued as COSV53907177; called by muse, mutect2, varscan2
- WDR20 | c.1431T>C p.D477= | Silent (SNP) | VAF 72/223 reads (32%) | catalogued as COSV54473393; called by muse, mutect2, varscan2
- CEP295 | chr11:93733544 C>T | 3'Flank (SNP) | VAF 5/17 reads (29%) | catalogued as rs572857017; called by muse, mutect2
- FAM174C | c.*312C>A | 3'UTR (SNP) | VAF 66/320 reads (21%) | catalogued as COSV101331213; called by muse, mutect2, varscan2
